Surgical pathology report (de-identified scan), TCGA case TCGA-24-1604, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1604-01A (Primary Tumor).

[page 1 of 3]
Name:

Address:

MR No.:

Service:

Surgeon:

Surg. Path. No.:

DOB:

Sex/Race:

Location:

Hosp. No.:

Taken/Received:

TCGA-24-1604

DIAGNOSIS

OVARY, RIGHT, BILATERAL SALPINGO-OOPHORECTOMY

- POORLY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA

OVARY, LEFT, BILATERAL SALPINGO-OOPHORECTOMY

- POORLY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA

- PARAOVARIAN ADHESIONS CONTAINING ADENOCARCINOMA

FALLOPIAN TUBE, RIGHT, BILATERAL SALPINGO-OOPHORECTOMY

- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA

EXTENSIVELY INVOLVING PERITUBAL SOFT TISSUE

- MILD HYDROSALPINX

FALLOPIAN TUBE, LEFT, BILATERAL SALPINGO-OOPHORECTOMY

- DETACHED FRAGMENTS OF ADENOCARCINOMA WITHIN THE
TUBAL LUMEN

OMENTUM, OMENTECTOMY - METASTATIC PAPILLARY SEROUS ADENOCARCINOMA

APPENDIX, APPENDECTOMY - METASTATIC PAPILLARY SEROUS ADENOCARCINOMA

EXTENSIVELY INVOLVING PERIAPPENDICEAL
SOFT TISSUE

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY

- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA

WITHIN A LYMPHATIC SPACE IN THE DEEP

PARACERVICAL SOFT TISSUE

- CHRONIC INFLAMMATION

- SQUAMOUS METAPLASIA

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- WELL DIFFERENTIATED ENDOMETRIOID ADENOCARCINOMA

(FIGO GRADE I) ARISING IN A BACKGROUND OF COMPLEX
HYPERPLASIA WITH ATYPIA

- NO DEFINITE MYOMETRIAL INVASION IDENTIFIED
(SEE COMMENT)

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY - ADENOMYOSIS

UTERUS, SEROSA, TOTAL ABDOMINAL HYSTERECTOMY

- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA

[page 2 of 3]
GROSS (continued)

posterior endometrium; US - posterior uterine serosa; RO1 to RO5 - tumor of the right ovary; RT1, RT2 - right fallopian tube; LO1 to LO3 - left ovary; LT - left fallopian tube.

The second container is labeled "omentum," and contains an irregular large fragment of omentum measuring 23.5 x 18.0 x 2.0 cm in overall dimensions, which is largely replaced by gray-brown, solid and firm tissue with a necrotic appearance. The firm area measures 1.9 cm in maximum diameter. Representative sections are submitted. [REDACTED]

The third container is labeled "appendix," and contains a segment of appendix measuring 4.5 cm in length and 1.0 cm in maximum diameter. The external surface is covered by gray-brown and necrotic exudate. On sectioning, the appendiceal wall is partially infiltrated by nodular, gray-brown, firm tumor tissue. The lumen appears grossly unremarkable. [REDACTED]

COMMENT

Poorly differentiated papillary serous adenocarcinoma is present in both ovaries, in right peritubal soft tissue, as detached fragments in the left tubal lumen, on the uterine serosa, extensively replacing the omentum, and in periappendiceal soft tissue. The endometrium shows extensive complex hyperplasia with atypia and multifocal areas of well-differentiated endometrioid adenocarcinoma (FIGO grade I). The endometrial-myometrial junction is quite irregular making assessment of invasion difficult, however, no definite invasion is identified. Adenocarcinoma does involve adenomyosis. No lymphovascular space invasion from the endometrial carcinoma is seen. This tumor in the endometrium is distinct morphologically from the tumor in the ovaries and other locations and represents a synchronous primary. The cervix is free of endometrial carcinoma, however, metastatic papillary serous adenocarcinoma is present within a lymphatic space in the deep paracervical soft tissue. [REDACTED]

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

1a. A neoplasm is PRESENT.

2. The HISTOLOGIC DIAGNOSIS is:

Serous adenocarcinoma [REDACTED]

3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are:

Right and left ovary (synchronous primary tumors) [REDACTED]

[page 3 of 3]
COMMENT (continued)

provisional, and may change after integration of clinical data not provided with this specimen.

SYNOPTIC REPORTING FORM FOR MALIGNANT ENDOMETRIAL TUMORS

1. A NEOPLASM IS:
Present
2. THE HISTOLOGIC DIAGNOSIS IS:
Adenocarcinoma, endometrioid type
3. THE MAXIMUM TUMOR SIZE IS 4.0 cm
4. THE LENGTH OF THE UTERINE CAVITY IS 4.0 cm
5. THE FIGO GRADE OF THE TUMOR IS:
FI (0 to 5% solid growth pattern)
6. THE NUCLEAR GRADE OF THE TUMOR IS:
NI
7. INVASIVE TUMOR IS:
Absent (intraendometrial tumor only)
8. THE TUMOR INVADES TO A DEPTH OF 0 mm
WITH A MYOMETRIAL THICKNESS OF 20 mm
9. THE ENDOCERVIX IS:
Uninvolved by tumor (see comment)
10. LYMPHATIC INVASION BY TUMOR IS:
Absent
11. VASCULAR INVASION BY TUMOR IS:
Absent
12. RESIDUAL NON-NEOPLASTIC ENDOMETRIAL TISSUE:
Shows complex hyperplasia with atypia
13. THE MYOMETRIUM:
Shows adenomyosis
14. THE RIGHT OVARY:
Contains a second primary tumor (papillary serous)
15. THE LEFT OVARY:
Contains a second primary tumor (papillary serous)
16. THE RIGHT FALLOPIAN TUBE:
Is involved by metastatic papillary serous cancer
17. THE LEFT FALLOPIAN TUBE:
Is involved by metastatic papillary serous cancer
18. THE VAGINAL CUFF OF EXCISION IS:
Not evaluable
19. TUMOR INVASION OF ADJACENT STRUCTURES IS:
Not evaluable
20. METASTASIS TO THE OMENTUM AND PERITONEUM IS:
Absent (see comment)
21. "T" DATA-- THE TUMOR IS:
T1 (Tumor confined to the uterine corpus)
22. THE REGIONAL LYMPH NODES:
Are not evaluable

Source: NCI Genomic Data Commons file 5d904ebc-11bc-418d-a04c-18279e67e7a6 (TCGA-24-1604.DE978A3D-92F9-4BD8-98F4-F8A3EC09B362.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).